Somatic mutation profile of tumor specimen TCGA-29-1691-01A (aliquot TCGA-29-1691-01A-01W-0633-09) from TCGA case TCGA-29-1691, project TCGA-OV (Ovarian Serous Cystadenocarcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Serous cystadenocarcinoma, NOS; Tissue or organ of origin: Ovary; FIGO stage: Stage IIIC; Tumor grade: G2; Age at diagnosis: 51.1 years (18,664 days).
Specimen TCGA-29-1691-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) dc28a500-7497-4d95-b561-fc5ba606eb3e.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-29-1691-10A (Blood Derived Normal), aliquot TCGA-29-1691-10A-01W-0633-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/fc63ce31-7b2f-4e05-bb13-687d79608bb0

The open-access MAF lists 220 somatic variants for this specimen: 175 protein-altering or splice-affecting, 39 silent, 6 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 150, Silent 39, Splice Site 9, Frame Shift Del 6, Nonsense Mutation 5, Splice Region 2, RNA 2, In Frame Del 2, Intron 1, 3'UTR 1, 5'UTR 1, 3'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- RB1 | c.1723C>T p.Q575* | Nonsense Mutation (SNP) | VAF 31/43 reads (72%) | catalogued as rs587778864, CM961232, COSV57303654; ClinVar: pathogenic; called by muse, mutect2, varscan2
- TP53 | c.681dup p.D228* | Frame Shift Ins (INS) | VAF 154/226 reads (68%) | catalogued as rs1567550002; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- ABCB4 | c.2620G>A p.E874K | Missense Mutation (SNP) | VAF 6/98 reads (6%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.926); catalogued as COSV99710725; called by muse, mutect2
- AC100868.1 | c.777C>A p.F259L | Missense Mutation (SNP) | VAF 26/66 reads (39%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.86); catalogued as COSV51841178; called by muse, mutect2, varscan2
- ACACB | c.2617G>C p.E873Q | Missense Mutation (SNP) | VAF 5/73 reads (7%) | SIFT deleterious (0.02); PolyPhen benign (0.369); catalogued as COSV100623068; called by muse, mutect2
- ADAM30 | c.1180G>A p.G394R | Missense Mutation (SNP) | VAF 251/519 reads (48%) | SIFT tolerated (0.24); PolyPhen benign (0.017); catalogued as COSV65560870; called by muse, mutect2, varscan2
- AF196969.1 | c.130G>A p.V44M | Missense Mutation (SNP) | VAF 18/133 reads (14%) | SIFT tolerated (0.06); PolyPhen benign (0.404); catalogued as rs782736490, COSV52141568; called by muse, mutect2, varscan2
- AGBL5 | c.2581T>C p.Y861H | Missense Mutation (SNP) | VAF 48/183 reads (26%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.005); catalogued as rs771435305, COSV64079556; called by muse, mutect2, varscan2
- ALG2 | c.1133G>C p.R378P | Missense Mutation (SNP) | VAF 20/140 reads (14%) | SIFT tolerated (0.11); PolyPhen benign (0.418); catalogued as COSV53059281; called by muse, mutect2, varscan2
- ALK | c.931C>T p.R311C | Missense Mutation (SNP) | VAF 28/398 reads (7%) | SIFT deleterious (0.03); PolyPhen benign (0.438); catalogued as rs149837139, COSV66578192; ClinVar: uncertain significance; called by muse, mutect2
- ALS2 | c.4529G>T p.R1510L | Missense Mutation (SNP) | VAF 13/196 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.928); catalogued as COSV99969013; called by muse, mutect2
- ANKS1A | c.1402T>G p.L468V | Missense Mutation (SNP) | VAF 27/160 reads (17%) | SIFT tolerated, low confidence (0.55); PolyPhen benign (0); catalogued as COSV64460062; called by muse, mutect2, varscan2
- AOX1 | c.2171A>T p.E724V | Missense Mutation (SNP) | VAF 43/358 reads (12%) | SIFT deleterious (0.04); PolyPhen benign (0.209); catalogued as COSV65981137; called by muse, mutect2, varscan2
- AP4E1 | c.1111G>T p.A371S | Missense Mutation (SNP) | VAF 39/73 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55916430; called by muse, mutect2, varscan2
- APC | c.3178A>G p.I1060V | Missense Mutation (SNP) | VAF 51/125 reads (41%) | SIFT tolerated, low confidence (0.41); PolyPhen benign (0.007); catalogued as COSV57338571; called by muse, mutect2, varscan2
- ASXL2 | c.2212G>C p.G738R | Missense Mutation (SNP) | VAF 32/368 reads (9%) | SIFT tolerated, low confidence (0.11); PolyPhen probably damaging (0.999); catalogued as COSV99711534; called by muse, mutect2
- ATP1A2 | c.1764G>C p.M588I | Missense Mutation (SNP) | VAF 12/162 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.697); catalogued as COSV100767935; called by muse, mutect2
- ATRAID | c.666G>T p.E222D (on ENST00000611786; = p.E109D on NM_016085.5) | Missense Mutation (SNP) | VAF 54/235 reads (23%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.99); catalogued as COSV104391635, COSV53025675; called by muse, mutect2, varscan2
- AXIN1 | c.926G>A p.G309D | Missense Mutation (SNP) | VAF 5/30 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1267777388, COSV99250023; called by muse, mutect2
- AXL | c.1506G>C p.K502N (on ENST00000301178 / NM_021913.5; = p.K493N on NM_001699.6) | Missense Mutation (SNP) | VAF 594/1028 reads (58%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV56567088; called by muse, varscan2
- BRWD3 | c.3481+2T>A p.X1161_splice | Splice Site (SNP) | VAF 21/83 reads (25%) | catalogued as COSV64746820; called by muse, mutect2, varscan2
- CCDC18 | c.3352C>T p.Q1118* (on ENST00000343253 / NM_001306076.1; = p.Q1119* on NM_206886.4) | Nonsense Mutation (SNP) | VAF 14/145 reads (10%) | catalogued as COSV100159734; called by mutect2, varscan2
- CCDC39 | c.623A>C p.K208T | Missense Mutation (SNP) | VAF 19/554 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV99869662; called by muse, mutect2
- CCP110 | c.678G>C p.M226I | Missense Mutation (SNP) | VAF 9/150 reads (6%) | SIFT tolerated (0.1); PolyPhen benign (0.003); catalogued as COSV101195301; called by muse, mutect2
- CD248 | c.1358T>C p.V453A | Missense Mutation (SNP) | VAF 21/43 reads (49%) | SIFT tolerated, low confidence (0.21); PolyPhen benign (0); catalogued as COSV60936245; called by muse, mutect2, varscan2
- CD80 | c.613G>T p.D205Y | Missense Mutation (SNP) | VAF 469/515 reads (91%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.983); catalogued as COSV51802031; called by muse, mutect2, varscan2
- CDC16 | c.859C>G p.L287V | Missense Mutation (SNP) | VAF 29/32 reads (91%) | SIFT tolerated (0.23); PolyPhen benign (0.227); catalogued as COSV52959182; called by muse, mutect2, varscan2
- CDH8 | c.236C>T p.P79L | Missense Mutation (SNP) | VAF 14/82 reads (17%) | SIFT deleterious (0.02); PolyPhen benign (0.023); catalogued as COSV54858989; called by muse, mutect2, varscan2
- CELSR1 | c.5722G>C p.V1908L | Missense Mutation (SNP) | VAF 6/17 reads (35%) | SIFT tolerated (0.06); PolyPhen benign (0.013); catalogued as COSV53087936, COSV53096104; called by muse, mutect2, varscan2
- CHN1 | c.665G>A p.C222Y | Missense Mutation (SNP) | VAF 4/18 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99789284; called by muse, mutect2
- COL23A1 | c.906G>T p.E302D | Missense Mutation (SNP) | VAF 36/152 reads (24%) | SIFT tolerated (0.08); PolyPhen benign (0.345); catalogued as COSV66789414; called by muse, mutect2, varscan2
- COL5A3 | c.896C>T p.P299L | Missense Mutation (SNP) | VAF 46/122 reads (38%) | SIFT tolerated (0.11); PolyPhen benign (0); catalogued as rs756130044, COSV53409332; called by muse, mutect2, varscan2
- COL9A1 | c.86C>A p.P29H | Missense Mutation (SNP) | VAF 32/46 reads (70%) | SIFT tolerated, low confidence (0.46); PolyPhen benign (0.319); catalogued as COSV61831183, COSV61831544; called by muse, mutect2, varscan2
- CSAD | c.1033G>A p.V345M (on ENST00000444623 / NM_001244705.2; = p.V372M on NM_015989.5) | Missense Mutation (SNP) | VAF 40/103 reads (39%) | SIFT deleterious (0.03); PolyPhen benign (0.365); catalogued as COSV57242181; called by muse, mutect2, varscan2
- CSMD1 | c.8032G>T p.A2678S (on ENST00000520002; = p.A2677S on NM_033225.6) | Missense Mutation (SNP) | VAF 50/278 reads (18%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.858); catalogued as COSV59295636, COSV59309970; called by muse, mutect2, varscan2
- CTR9 | c.2458T>G p.L820V | Missense Mutation (SNP) | VAF 23/41 reads (56%) | SIFT deleterious (0); PolyPhen possibly damaging (0.49); catalogued as COSV63728385; called by muse, mutect2, varscan2
- CXCL8 | c.116C>T p.T39I | Missense Mutation (SNP) | VAF 16/85 reads (19%) | SIFT tolerated (0.06); PolyPhen benign (0.022); catalogued as COSV56640949; called by muse, mutect2, varscan2
- CYP20A1 | c.22G>T p.A8S | Missense Mutation (SNP) | VAF 5/20 reads (25%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.94); catalogued as COSV61909352; called by muse, mutect2, varscan2
- DGKG | c.831G>T p.K277N | Missense Mutation (SNP) | VAF 10/143 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99403707; called by muse, mutect2
- DNAH10 | c.8992G>A p.G2998R (on ENST00000409039; = p.G2937R on NM_207437.3) | Missense Mutation (SNP) | VAF 57/167 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV68991839; called by muse, mutect2, varscan2
- DNAH11 | c.478T>C p.S160P | Missense Mutation (SNP) | VAF 4/11 reads (36%) | SIFT tolerated (0.19); PolyPhen benign (0.104); catalogued as COSV60951849; called by muse, mutect2, varscan2
- DNAI3 | c.1195G>A p.D399N | Missense Mutation (SNP) | VAF 56/193 reads (29%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.991); catalogued as COSV54001903; called by muse, mutect2, varscan2
- DNALI1 | c.20C>T p.A7V | Missense Mutation (SNP) | VAF 10/90 reads (11%) | SIFT tolerated, low confidence (0.31); PolyPhen benign (0.023); catalogued as COSV56166225; called by muse, mutect2
- DNM3 | c.801T>G p.H267Q | Missense Mutation (SNP) | VAF 59/136 reads (43%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); catalogued as COSV62455284, COSV62456514; called by muse, mutect2, varscan2
- DOCK10 | c.6350G>A p.R2117H | Missense Mutation (SNP) | VAF 33/81 reads (41%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.98); catalogued as rs771118606, COSV51376188; called by muse, mutect2, varscan2
- EBF3 | c.300C>A p.N100K | Missense Mutation (SNP) | VAF 9/19 reads (47%) | SIFT tolerated (0.18); PolyPhen benign (0.028); catalogued as COSV62473978; called by muse, mutect2, varscan2
- EHD2 | c.535G>T p.A179S | Missense Mutation (SNP) | VAF 55/137 reads (40%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.994); catalogued as COSV54407896, COSV99621506; called by muse, mutect2, varscan2
- EIF4G3 | c.2635G>T p.E879* | Nonsense Mutation (SNP) | VAF 36/130 reads (28%) | catalogued as COSV51679857; called by muse, mutect2, varscan2
- ELL3 | c.218T>C p.V73A | Missense Mutation (SNP) | VAF 15/25 reads (60%) | SIFT deleterious (0.04); PolyPhen benign (0.046); catalogued as rs1166007130, COSV55855584; called by muse, mutect2, varscan2
- EMB | c.283G>A p.D95N | Missense Mutation (SNP) | VAF 28/405 reads (7%) | SIFT tolerated (0.41); PolyPhen benign (0.058); catalogued as COSV57484680; called by muse, mutect2
- FCAMR | c.1559G>T p.W520L (on ENST00000324852 / NM_001170631.2; = p.G253* on NM_032029.4) | Missense Mutation (SNP) | VAF 105/225 reads (47%) | SIFT tolerated (0.68); PolyPhen benign (0.003); catalogued as COSV61367411, COSV61367444; called by muse, mutect2, varscan2
- FLG | c.3616G>A p.A1206T | Missense Mutation (SNP) | VAF 115/429 reads (27%) | SIFT tolerated (0.22); PolyPhen benign (0.111); catalogued as rs776312273, COSV64240359; called by muse, mutect2, varscan2
- FXR1 | c.634A>T p.T212S | Missense Mutation (SNP) | VAF 10/202 reads (5%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV99976471; called by muse, mutect2
- GALE | c.379C>A p.L127M | Missense Mutation (SNP) | VAF 8/43 reads (19%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.568); catalogued as COSV52525617; called by muse, mutect2, varscan2
- GCN1 | c.2234C>T p.T745I | Missense Mutation (SNP) | VAF 5/65 reads (8%) | SIFT tolerated (0.45); PolyPhen benign (0); catalogued as COSV100325528; called by muse, mutect2
- GNPAT | c.911A>T p.K304I | Missense Mutation (SNP) | VAF 13/103 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV64153285; called by muse, mutect2, varscan2
- GORASP2 | c.567-1G>C p.X189_splice | Splice Site (SNP) | VAF 29/86 reads (34%) | catalogued as COSV52201580; called by muse, mutect2, varscan2
- GRIN2A | c.812A>T p.E271V | Missense Mutation (SNP) | VAF 24/256 reads (9%) | SIFT tolerated (0.34); PolyPhen benign (0.003); catalogued as COSV100410301; called by muse, mutect2
- HABP2 | c.1236T>C p.I412= | Splice Region (SNP) | VAF 35/90 reads (39%) | catalogued as rs1175891680, COSV63636420; called by muse, mutect2, varscan2
- HEATR1 | c.1924G>C p.E642Q | Missense Mutation (SNP) | VAF 10/29 reads (34%) | SIFT tolerated (0.15); PolyPhen benign (0.09); catalogued as COSV63980235, COSV63980720; called by muse, varscan2
- HEPH | c.2163C>A p.H721Q (on ENST00000343002; = p.H454Q on NM_014799.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 18/255 reads (7%) | SIFT tolerated (0.6); PolyPhen benign (0); catalogued as COSV100295120; called by muse, mutect2
- HPS3 | c.2974C>T p.P992S | Missense Mutation (SNP) | VAF 11/242 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99224248; called by muse, mutect2
- HTR2A | c.1365G>C p.E455D | Missense Mutation (SNP) | VAF 66/88 reads (75%) | SIFT tolerated (0.25); PolyPhen benign (0); catalogued as COSV66327063; called by muse, mutect2, varscan2
- HTT | c.8546C>T p.P2849L | Missense Mutation (SNP) | VAF 13/72 reads (18%) | SIFT deleterious (0.02); PolyPhen benign (0.171); catalogued as rs144891713; called by muse, mutect2, varscan2
- IGSF21 | c.862C>T p.R288C | Missense Mutation (SNP) | VAF 105/309 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.683); catalogued as rs752370692, COSV52130811; called by muse, mutect2, varscan2
- IPP | c.29C>G p.A10G | Missense Mutation (SNP) | VAF 24/115 reads (21%) | SIFT tolerated, low confidence (0.74); PolyPhen benign (0); catalogued as COSV63432425; called by muse, mutect2, varscan2
- IRAK1BP1 | c.15G>C p.K5N | Missense Mutation (SNP) | VAF 10/175 reads (6%) | SIFT tolerated, low confidence (0.36); PolyPhen benign (0.003); catalogued as COSV100884894; called by muse, mutect2
- ITGA10 | c.716del p.E239Gfs*11 | Frame Shift Del (DEL) | VAF 100/591 reads (17%) | catalogued as COSV65196807; called by mutect2, pindel, varscan2
- ITGAL | c.2981C>G p.P994R | Missense Mutation (SNP) | VAF 11/96 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV63321728, COSV63322976; called by muse, mutect2, varscan2
- JAKMIP1 | c.373G>A p.A125T | Missense Mutation (SNP) | VAF 3/18 reads (17%) | SIFT tolerated (0.33); PolyPhen benign (0.23); catalogued as COSV99290012; called by muse, mutect2
- KCNC4 | c.1477A>G p.K493E | Missense Mutation (SNP) | VAF 49/143 reads (34%) | SIFT deleterious (0.01); PolyPhen benign (0.082); catalogued as COSV63925502; called by muse, mutect2, varscan2
- KCNV1 | c.626C>T p.A209V | Missense Mutation (SNP) | VAF 42/96 reads (44%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.825); catalogued as COSV52085692; called by muse, mutect2, varscan2
- KIAA1109 | c.9487G>C p.G3163R | Missense Mutation (SNP) | VAF 37/124 reads (30%) | SIFT tolerated (0.67); PolyPhen probably damaging (0.999); catalogued as rs1217216865, COSV52669323; called by muse, mutect2, varscan2
- KIF21B | c.3947C>T p.A1316V (on ENST00000422435 / NM_001252100.2; = p.A1303V on NM_017596.4) | Missense Mutation (SNP) | VAF 12/86 reads (14%) | SIFT tolerated (0.25); PolyPhen probably damaging (0.996); catalogued as COSV59756013; called by muse, mutect2, varscan2
- KMT2C | c.10462A>T p.I3488L | Missense Mutation (SNP) | VAF 62/468 reads (13%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV51429637; called by muse, mutect2, varscan2
- KRT71 | c.1184A>T p.D395V | Missense Mutation (SNP) | VAF 14/188 reads (7%) | SIFT tolerated (0.22); PolyPhen probably damaging (0.974); catalogued as COSV57293935, COSV99922273; called by muse, mutect2
- LGALS3BP | c.1045C>T p.P349S | Missense Mutation (SNP) | VAF 4/37 reads (11%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.986); catalogued as COSV99431770; called by muse, mutect2
- LTF | c.1070T>A p.V357E | Missense Mutation (SNP) | VAF 9/35 reads (26%) | SIFT tolerated (1); PolyPhen benign (0.063); catalogued as rs1225849122, COSV99209197; called by muse, varscan2
- LTN1 | c.884C>G p.S295C | Missense Mutation (SNP) | VAF 87/240 reads (36%) | SIFT tolerated (0.06); PolyPhen benign (0.319); catalogued as COSV63733531; called by muse, mutect2, varscan2
- MCM10 | c.791A>G p.E264G (on ENST00000484800 / NM_182751.3; = p.E263G on NM_018518.5) | Missense Mutation (SNP) | VAF 61/197 reads (31%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.943); catalogued as COSV66333903; called by muse, mutect2, varscan2
- MIOX | c.314G>A p.G105D | Missense Mutation (SNP) | VAF 8/10 reads (80%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.917); catalogued as COSV53312609; called by muse, mutect2, varscan2
- MOB1A | c.524A>T p.E175V | Missense Mutation (SNP) | VAF 16/239 reads (7%) | SIFT tolerated (0.38); PolyPhen benign (0.045); catalogued as COSV101247292; called by muse, mutect2
- MPP3 | c.1538C>T p.T513M | Missense Mutation (SNP) | VAF 42/170 reads (25%) | SIFT tolerated (0.09); PolyPhen benign (0.017); catalogued as rs202078532; called by muse, mutect2, varscan2
- MRC2 | c.3949C>A p.H1317N | Missense Mutation (SNP) | VAF 11/13 reads (85%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.847); catalogued as COSV57638862; called by muse, mutect2, varscan2
- MSANTD3 | c.625C>A p.Q209K | Missense Mutation (SNP) | VAF 38/262 reads (15%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.292); catalogued as rs1427439697, COSV58492492; called by muse, mutect2, varscan2
- MTMR3 | c.2837G>C p.S946T | Missense Mutation (SNP) | VAF 10/157 reads (6%) | SIFT tolerated, low confidence (0.39); PolyPhen benign (0); catalogued as COSV100070993; called by muse, mutect2
- MTOR | c.2261C>G p.A754G | Missense Mutation (SNP) | VAF 63/198 reads (32%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.646); catalogued as COSV63870200; called by muse, mutect2, varscan2
- MUC16 | c.20825A>G p.K6942R | Missense Mutation (SNP) | VAF 58/277 reads (21%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0.181); catalogued as COSV67459996; called by muse, mutect2, varscan2
- MUC5B | c.7528G>A p.A2510T | Missense Mutation (SNP) | VAF 9/30 reads (30%) | SIFT tolerated (0.31); PolyPhen benign (0.007); catalogued as rs763935457, COSV71591357; called by muse, mutect2, varscan2
- MYRIP | c.34G>A p.D12N | Missense Mutation (SNP) | VAF 32/154 reads (21%) | SIFT deleterious (0.03); PolyPhen benign (0.154); catalogued as COSV56866878; called by muse, mutect2, varscan2
- NASP | c.2204C>T p.A735V | Missense Mutation (SNP) | VAF 11/84 reads (13%) | SIFT tolerated (0.09); PolyPhen benign (0.132); catalogued as COSV59646794; called by muse, mutect2, varscan2
- NCOA2 | c.1330T>A p.S444T | Missense Mutation (SNP) | VAF 20/144 reads (14%) | SIFT tolerated (0.49); PolyPhen benign (0.206); catalogued as COSV71763827; called by muse, mutect2, varscan2
- NDST2 | c.1578G>T p.M526I | Missense Mutation (SNP) | VAF 8/75 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.694); catalogued as COSV55213920; called by muse, mutect2, varscan2
- NFE2L3 | c.1375C>G p.H459D | Missense Mutation (SNP) | VAF 97/253 reads (38%) | SIFT tolerated (0.17); PolyPhen benign (0.003); catalogued as COSV50227181; called by muse, mutect2, varscan2
- NLGN3 | c.1307T>C p.F436S (on ENST00000358741 / NM_181303.2; = p.F416S on NM_018977.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 105/372 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.958); catalogued as COSV100704530, COSV62442621; called by muse, mutect2, varscan2
- NOS1AP | c.1086G>C p.K362N | Missense Mutation (SNP) | VAF 6/92 reads (7%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.879); catalogued as COSV100723414; called by muse, mutect2
- NR1I3 | c.930G>T p.R310= (on ENST00000367982 / NM_001077480.3; = p.R306= on NM_005122.5) | Splice Region (SNP) | VAF 173/427 reads (41%) | catalogued as rs760125469, COSV63467648; called by muse, mutect2, varscan2
- NRBF2 | c.725C>A p.T242N | Missense Mutation (SNP) | VAF 29/106 reads (27%) | SIFT deleterious (0.02); PolyPhen benign (0.119); catalogued as COSV53258955; called by muse, mutect2, varscan2
- NSD1 | c.6152-2A>C p.X2051_splice | Splice Site (SNP) | VAF 33/103 reads (32%) | catalogued as COSV61774826; called by muse, mutect2, varscan2
- OAS3 | c.643C>G p.L215V | Missense Mutation (SNP) | VAF 8/35 reads (23%) | SIFT tolerated (0.13); PolyPhen benign (0.018); catalogued as COSV57445202; called by muse, mutect2, varscan2
- ODC1 | c.493C>T p.R165C | Missense Mutation (SNP) | VAF 58/126 reads (46%) | SIFT tolerated (0.2); PolyPhen benign (0.001); catalogued as rs754387209, COSV52172100; called by muse, mutect2, varscan2
- OR10C1 | c.46C>T p.L16F (on ENST00000622521; = p.L14F on NM_013941.3) | Missense Mutation (SNP) | VAF 56/736 reads (8%) | SIFT deleterious (0.02); PolyPhen benign (0.436); catalogued as rs765131882, COSV65823508, COSV65823972; called by muse, mutect2
- OR11H4 | c.950G>C p.G317A | Missense Mutation (SNP) | VAF 31/66 reads (47%) | SIFT tolerated (0.38); PolyPhen benign (0.001); catalogued as rs1293977853, COSV59560167; called by muse, mutect2, varscan2
- OR4A15 | c.404A>G p.N135S | Missense Mutation (SNP) | VAF 133/811 reads (16%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0.045); catalogued as rs369716493; called by muse, mutect2, varscan2
- PAQR6 | c.139A>G p.N47D | Missense Mutation (SNP) | VAF 4/37 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99431316; called by muse, mutect2
- PCDHB8 | c.481T>G p.L161V | Missense Mutation (SNP) | VAF 6/60 reads (10%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.151); catalogued as COSV99177113; called by muse, mutect2, varscan2
- PCK2 | c.1429G>T p.A477S | Missense Mutation (SNP) | VAF 6/23 reads (26%) | SIFT tolerated (0.68); PolyPhen benign (0.059); catalogued as COSV53749514, COSV99394484; called by mutect2, varscan2
- PDE6A | c.2356A>G p.K786E | Missense Mutation (SNP) | VAF 100/111 reads (90%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.874); catalogued as COSV54926522; called by muse, mutect2, varscan2
- PHF12 | c.2525G>A p.C842Y | Missense Mutation (SNP) | VAF 38/72 reads (53%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.99); catalogued as rs1431914474, COSV52018908; called by muse, mutect2, varscan2
- PHF14 | c.539C>T p.P180L | Missense Mutation (SNP) | VAF 14/131 reads (11%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); catalogued as COSV68855008; called by muse, mutect2, varscan2
- PI4KB | c.77G>A p.G26E (on ENST00000368873 / NM_001369623.1; = p.G38E on NM_002651.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 90/371 reads (24%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.074); catalogued as COSV55016723; called by muse, mutect2, varscan2
- PIAS2 | c.610G>T p.D204Y | Missense Mutation (SNP) | VAF 11/27 reads (41%) | SIFT deleterious (0); PolyPhen benign (0.445); catalogued as COSV61342905; called by muse, mutect2, varscan2
- PPFIA2 | c.2629A>T p.R877* | Nonsense Mutation (SNP) | VAF 24/47 reads (51%) | catalogued as COSV61028713, COSV61056585; called by muse, mutect2, varscan2
- PRG2 | c.221T>C p.V74A | Missense Mutation (SNP) | VAF 58/531 reads (11%) | SIFT tolerated (0.3); PolyPhen benign (0.057); catalogued as COSV61293441; called by muse, mutect2, varscan2
- PRSS55 | c.558G>T p.W186C | Missense Mutation (SNP) | VAF 71/118 reads (60%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60808095; called by muse, mutect2, varscan2
- PSD3 | c.1350C>A p.D450E | Missense Mutation (SNP) | VAF 66/197 reads (34%) | SIFT tolerated (0.47); PolyPhen benign (0.057); catalogued as COSV58967039; called by muse, mutect2, varscan2
- PTCHD4 | c.199G>A p.E67K | Missense Mutation (SNP) | VAF 5/20 reads (25%) | SIFT deleterious (0); PolyPhen benign (0.097); catalogued as rs1410865996, COSV59780568; called by muse, mutect2, varscan2
- RAD54L | c.805C>T p.P269S | Missense Mutation (SNP) | VAF 77/247 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.977); catalogued as COSV100914786, COSV64335867; called by muse, mutect2, varscan2
- RANBP2 | c.1963G>C p.A655P | Missense Mutation (SNP) | VAF 54/210 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as COSV51699555; called by muse, mutect2, varscan2
- RASGRF1 | c.2916C>G p.N972K | Missense Mutation (SNP) | VAF 122/251 reads (49%) | SIFT deleterious (0.02); PolyPhen benign (0.067); catalogued as COSV67249809; called by muse, mutect2, varscan2
- RBSN | c.1819G>C p.G607R | Missense Mutation (SNP) | VAF 11/96 reads (11%) | SIFT tolerated, low confidence (0.37); PolyPhen benign (0); catalogued as COSV53792550; called by muse, mutect2, varscan2
- RPTN | c.656C>A p.A219D | Missense Mutation (SNP) | VAF 529/1126 reads (47%) | SIFT tolerated (0.12); PolyPhen benign (0.023); catalogued as COSV60166979; called by muse, mutect2, varscan2
- RTL9 | c.2699C>A p.P900Q | Missense Mutation (SNP) | VAF 383/823 reads (47%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.839); catalogued as COSV71825492; called by muse, mutect2, varscan2
- SATB2 | c.1817C>T p.P606L | Missense Mutation (SNP) | VAF 21/174 reads (12%) | SIFT deleterious (0.03); PolyPhen benign (0.003); catalogued as COSV53482064; called by muse, mutect2, varscan2
- SCN3A | c.3196G>C p.D1066H | Missense Mutation (SNP) | VAF 31/142 reads (22%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.473); catalogued as rs1342644388, COSV51807394; called by muse, mutect2, varscan2
- SCN8A | c.971G>A p.C324Y | Missense Mutation (SNP) | VAF 9/126 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.897); catalogued as COSV100633988; called by muse, mutect2
- SERPINB2 | c.677C>G p.S226W | Missense Mutation (SNP) | VAF 44/102 reads (43%) | SIFT deleterious (0); PolyPhen possibly damaging (0.772); catalogued as COSV55091984; called by muse, mutect2, varscan2
- SERPINB3 | c.613-1G>T p.X205_splice | Splice Site (SNP) | VAF 15/142 reads (11%) | catalogued as COSV52190439, COSV52191013; called by muse, mutect2, varscan2
- SH3PXD2A | c.2321A>T p.D774V (on ENST00000369774 / NM_001365079.1; = p.D746V on NM_014631.2) | Missense Mutation (SNP) | VAF 7/112 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100280213; called by muse, mutect2
- SHROOM4 | c.3004_3034del p.H1002Cfs*20 | Frame Shift Del (DEL) | VAF 30/145 reads (21%) | catalogued as COSV56787934; called by mutect2, pindel, varscan2
- SIPA1L1 | c.2735C>T p.T912I | Missense Mutation (SNP) | VAF 50/133 reads (38%) | SIFT tolerated (0.13); PolyPhen benign (0.014); catalogued as COSV62169573; called by muse, mutect2, varscan2
- SIPA1L2 | c.3601A>G p.K1201E | Missense Mutation (SNP) | VAF 52/465 reads (11%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.525); catalogued as COSV53388574; called by muse, mutect2
- SLC43A3 | c.793C>T p.Q265* | Nonsense Mutation (SNP) | VAF 68/315 reads (22%) | catalogued as COSV61450206; called by muse, mutect2, varscan2
- SLC44A1 | c.1340C>G p.S447C | Missense Mutation (SNP) | VAF 36/287 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.924); catalogued as COSV58263865, COSV58267309; called by muse, mutect2, varscan2
- SLC5A12 | c.263A>T p.Y88F | Missense Mutation (SNP) | VAF 11/300 reads (4%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.819); catalogued as COSV99745131; called by muse, mutect2
- SLCO1C1 | c.737G>A p.C246Y | Missense Mutation (SNP) | VAF 20/48 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); catalogued as COSV56871265; called by muse, mutect2, varscan2
- SORCS3 | c.698C>T p.S233L | Missense Mutation (SNP) | VAF 75/209 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1409279522, COSV63807710; called by muse, mutect2, varscan2
- SRRM2 | c.7168T>C p.Y2390H | Missense Mutation (SNP) | VAF 116/250 reads (46%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.991); catalogued as COSV51940430; called by muse, mutect2, varscan2
- STX16 | c.265G>A p.V89I (on ENST00000371141 / NM_001001433.3; = p.V68I on NM_003763.6) | Missense Mutation (SNP) | VAF 92/107 reads (86%) | SIFT tolerated (1); PolyPhen benign (0.007); catalogued as COSV56605082; called by muse, mutect2, varscan2
- SYNE1 | c.739G>A p.E247K (on ENST00000367255 / NM_182961.4; = p.E254K on NM_033071.3) | Missense Mutation (SNP) | VAF 16/150 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs756083475, COSV54958340; called by muse, mutect2, varscan2
- SYNE2 | c.16592C>A p.P5531H | Missense Mutation (SNP) | VAF 15/108 reads (14%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.865); catalogued as COSV59947286; called by muse, mutect2, varscan2
- TAS2R1 | c.739C>A p.L247I | Missense Mutation (SNP) | VAF 25/177 reads (14%) | SIFT tolerated (0.47); PolyPhen benign (0.056); catalogued as COSV66778345; called by muse, mutect2, varscan2
- TCTEX1D2 | c.404C>G p.A135G | Missense Mutation (SNP) | VAF 12/216 reads (6%) | SIFT deleterious (0); PolyPhen benign (0.285); catalogued as COSV99492280; called by muse, mutect2
- TIGD2 | c.1207G>A p.G403R | Missense Mutation (SNP) | VAF 21/52 reads (40%) | SIFT tolerated (0.42); PolyPhen benign (0.321); catalogued as rs745849749, COSV57647588; called by muse, mutect2, varscan2
- TMC2 | c.451G>C p.E151Q | Missense Mutation (SNP) | VAF 17/147 reads (12%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.815); catalogued as COSV62651837, COSV62656564; called by muse, mutect2, varscan2
- TMEM119 | c.191C>T p.P64L | Missense Mutation (SNP) | VAF 18/20 reads (90%) | SIFT tolerated (0.08); PolyPhen benign (0.011); catalogued as COSV67188620; called by muse, mutect2, varscan2
- TMEM267 | c.272A>G p.D91G | Missense Mutation (SNP) | VAF 40/217 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV67992608; called by muse, mutect2, varscan2
- TRIM55 | c.269A>C p.H90P | Missense Mutation (SNP) | VAF 49/299 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as COSV52545423; called by muse, mutect2, varscan2
- TRPM4 | c.1474A>G p.K492E | Missense Mutation (SNP) | VAF 15/37 reads (41%) | SIFT tolerated (0.85); PolyPhen benign (0.001); catalogued as rs1403797682, COSV53261936; called by muse, mutect2, varscan2
- TSHZ3 | c.2920C>G p.P974A | Missense Mutation (SNP) | VAF 25/172 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV53669118; called by muse, mutect2, varscan2
- TTC21B | c.552+1G>T p.X184_splice | Splice Site (SNP) | VAF 21/117 reads (18%) | catalogued as COSV54629566; called by muse, mutect2, varscan2
- USP40 | c.1840G>T p.A614S | Missense Mutation (SNP) | VAF 11/34 reads (32%) | SIFT tolerated (0.16); PolyPhen benign (0.118); catalogued as COSV52479687; called by muse, mutect2, varscan2
- VCAN | c.8266C>A p.H2756N | Missense Mutation (SNP) | VAF 61/67 reads (91%) | SIFT tolerated (0.32); PolyPhen benign (0.057); catalogued as rs913320204, COSV99426361; called by muse, mutect2, varscan2
- VDAC3 | c.614C>A p.S205Y | Missense Mutation (SNP) | VAF 42/166 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.876); catalogued as COSV50081381, COSV99195137; called by muse, mutect2, varscan2
- WDR3 | c.955G>A p.D319N | Missense Mutation (SNP) | VAF 30/160 reads (19%) | SIFT tolerated (0.44); PolyPhen benign (0.045); catalogued as COSV62523085; called by muse, mutect2, varscan2
- XPNPEP1 | c.1910A>C p.D637A | Missense Mutation (SNP) | VAF 34/104 reads (33%) | SIFT tolerated (0.19); PolyPhen benign (0.022); catalogued as COSV59167596; called by muse, varscan2
- ZNF233 | c.1870A>T p.M624L | Missense Mutation (SNP) | VAF 31/295 reads (11%) | SIFT tolerated (0.21); PolyPhen benign (0.038); catalogued as COSV61933478; called by muse, mutect2
- ZNF773 | c.116T>C p.L39P | Missense Mutation (SNP) | VAF 184/226 reads (81%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56588231; called by muse, mutect2, varscan2
- ZNF793 | c.44T>C p.V15A | Missense Mutation (SNP) | VAF 12/344 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV101495677; called by muse, mutect2
- ZNF827 | c.23A>G p.Q8R | Missense Mutation (SNP) | VAF 13/67 reads (19%) | SIFT tolerated, low confidence (0.07); PolyPhen possibly damaging (0.901); catalogued as COSV65226308; called by muse, mutect2, varscan2
- ZSCAN20 | c.2954A>G p.K985R | Missense Mutation (SNP) | VAF 53/170 reads (31%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.876); catalogued as rs1467249827, COSV63682342; called by muse, mutect2, varscan2
- ZSCAN32 | c.1040G>A p.G347E (on ENST00000396846; = p.G368E on NM_017810.4 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 74/289 reads (26%) | SIFT tolerated (0.13); PolyPhen benign (0.025); catalogued as COSV59234873; called by muse, mutect2, varscan2
- BOD1L1 | c.7993_8019+21del p.X2665_splice | Splice Site (DEL) | VAF 8/46 reads (17%) | called by mutect2, pindel
- DDX58 | c.877_921del p.V293_K307del | In Frame Del (DEL) | VAF 10/126 reads (8%) | called by mutect2, pindel
- IL10 | c.445-3_475del p.X149_splice | Splice Site (DEL) | VAF 9/37 reads (24%) | called by mutect2, pindel, varscan2
- INTS12 | c.125_137del p.G42Vfs*47 | Frame Shift Del (DEL) | VAF 46/377 reads (12%) | called by mutect2, pindel
- KLHL15 | c.617G>A p.R206Q | Missense Mutation (SNP) | VAF 55/948 reads (6%) | SIFT tolerated (0.25); PolyPhen benign (0.083); called by muse, mutect2
- KRT13 | c.761_787del p.V254_M262del | In Frame Del (DEL) | VAF 262/942 reads (28%) | called by mutect2, pindel, varscan2
- NMD3 | c.1417_1433del p.E473* | Frame Shift Del (DEL) | VAF 61/374 reads (16%) | called by mutect2, pindel, varscan2
- PHF8 | c.563-20_563-1del p.X188_splice (on ENST00000357988 / NM_001184896.1; = p.X152_splice on NM_015107.3) | Splice Site (DEL) | VAF 49/240 reads (20%) | called by pindel, varscan2
- PMM1 | c.538A>G p.R180G | Missense Mutation (SNP) | VAF 4/14 reads (29%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.474); called by muse, mutect2
- SLC25A45 | c.154-33_161del p.X52_splice | Splice Site (DEL) | VAF 26/32 reads (81%) | called by mutect2, pindel
- TEX11 | c.349A>T p.S117C (on ENST00000344304; = p.S102C on NM_031276.3) | Missense Mutation (SNP) | VAF 8/150 reads (5%) | SIFT deleterious (0.04); PolyPhen benign (0.121); called by muse, mutect2
- TMEM132B | c.411_427del p.Q137Hfs*7 | Frame Shift Del (DEL) | VAF 92/206 reads (45%) | called by mutect2, pindel, varscan2
- TSNAXIP1 | c.227_252del p.P76Hfs*19 | Frame Shift Del (DEL) | VAF 11/51 reads (22%) | called by mutect2, pindel, varscan2
- ACOT12 | c.324C>T p.F108= | Silent (SNP) | VAF 20/34 reads (59%) | catalogued as COSV56894344; called by muse, mutect2, varscan2
- ANKRD34A | c.705A>G p.P235= | Silent (SNP) | VAF 102/360 reads (28%) | catalogued as COSV60160769; called by muse, mutect2, varscan2
- ASPM | c.4125C>A p.I1375= | Silent (SNP) | VAF 4/77 reads (5%) | catalogued as COSV99660652; called by muse, mutect2
- C1QTNF9 | c.138C>T p.D46= | Silent (SNP) | VAF 29/113 reads (26%) | catalogued as rs374313886; called by muse, mutect2, varscan2
- C1QTNF9B | c.138C>T p.D46= | Silent (SNP) | VAF 41/307 reads (13%) | catalogued as rs374662312; called by muse, mutect2, varscan2
- CXCR5 | c.609C>G p.T203= | Silent (SNP) | VAF 33/139 reads (24%) | catalogued as COSV52683601; called by muse, mutect2, varscan2
- DCAF12L2 | c.321C>T p.N107= | Silent (SNP) | VAF 9/50 reads (18%) | catalogued as COSV63581208; called by muse, mutect2, varscan2
- DIP2C | c.2049G>A p.L683= | Silent (SNP) | VAF 24/193 reads (12%) | catalogued as COSV55154269; called by muse, mutect2, varscan2
- DISP2 | c.1467G>T p.T489= | Silent (SNP) | VAF 32/38 reads (84%) | catalogued as COSV51119485; called by muse, mutect2, varscan2
- EMP2 | c.498C>G p.R166= | Silent (SNP) | VAF 34/140 reads (24%) | catalogued as rs1190433553, COSV63995824; called by muse, mutect2, varscan2
- EXOSC10 | c.2409G>A p.K803= (on ENST00000376936 / NM_001001998.3; = p.K778= on NM_002685.4) | Silent (SNP) | VAF 106/755 reads (14%) | catalogued as COSV58664997; called by muse, mutect2, varscan2
- FCGBP | c.3042G>C p.L1014= | Silent (SNP) | VAF 18/204 reads (9%) | called by muse, mutect2
- GPRIN1 | c.294C>T p.C98= | Silent (SNP) | VAF 11/33 reads (33%) | catalogued as rs531996464, COSV56137550; called by muse, mutect2, varscan2
- HDX | c.832C>T p.L278= | Silent (SNP) | VAF 70/254 reads (28%) | catalogued as COSV52975584; called by muse, mutect2, varscan2
- HEATR9 | c.129C>T p.S43= | Silent (SNP) | VAF 44/243 reads (18%) | catalogued as rs113048475; called by muse, mutect2, varscan2
- HIP1 | c.837G>A p.L279= | Silent (SNP) | VAF 15/37 reads (41%) | catalogued as COSV61185039; called by muse, mutect2, varscan2
- HMMR | c.1689T>A p.A563= | Silent (SNP) | VAF 35/91 reads (38%) | catalogued as COSV62374323; called by muse, mutect2, varscan2
- HUWE1 | c.3337T>C p.L1113= | Silent (SNP) | VAF 14/87 reads (16%) | catalogued as COSV53342359; called by muse, mutect2, varscan2
- JPH4 | c.1359C>T p.P453= | Silent (SNP) | VAF 72/118 reads (61%) | catalogued as rs1293266714, COSV58111988; called by muse, mutect2, varscan2
- KDM5B | c.4257C>T p.L1419= | Silent (SNP) | VAF 8/120 reads (7%) | catalogued as rs1163947628, COSV99350909; called by muse, mutect2
- LYAR | c.24A>C p.A8= | Silent (SNP) | VAF 39/65 reads (60%) | catalogued as COSV58642620; called by muse, mutect2, varscan2
- MAST2 | c.1590G>T p.R530= | Silent (SNP) | VAF 40/48 reads (83%) | catalogued as COSV63617618; called by muse, mutect2, varscan2
- NR5A2 | c.615T>C p.S205= (on ENST00000367362 / NM_205860.3; = p.S159= on NM_003822.5) | Silent (SNP) | VAF 117/256 reads (46%) | catalogued as rs777713696, COSV52648671; called by muse, mutect2, varscan2
- OR10C1 | c.45T>C p.L15= (on ENST00000622521; = p.L13= on NM_013941.3) | Silent (SNP) | VAF 56/732 reads (8%) | catalogued as COSV101010853; called by muse, mutect2
- OR6N1 | c.114T>C p.T38= | Silent (SNP) | VAF 78/345 reads (23%) | catalogued as COSV58647994; called by muse, mutect2, varscan2
- POU2F1 | c.2193G>C p.G731= (on ENST00000541643 / NM_001365848.1; = p.G754= on NM_002697.4) | Silent (SNP) | VAF 27/276 reads (10%) | catalogued as COSV99611421; called by muse, mutect2
- PRPF3 | c.1554A>T p.R518= | Silent (SNP) | VAF 185/426 reads (43%) | catalogued as COSV61394531; called by muse, mutect2, varscan2
- RLIM | c.27A>G p.K9= | Silent (SNP) | VAF 23/91 reads (25%) | catalogued as COSV60326120; called by muse, mutect2, varscan2
- RNF121 | c.393C>G p.T131= | Silent (SNP) | VAF 221/261 reads (85%) | catalogued as COSV62316526; called by muse, mutect2, varscan2
- RPS6KA3 | c.2166C>T p.G722= | Silent (SNP) | VAF 7/182 reads (4%) | catalogued as COSV101084474; called by muse, mutect2
- SCN3A | c.1485T>C p.S495= | Silent (SNP) | VAF 18/322 reads (6%) | catalogued as COSV99327473; called by muse, mutect2
- SKA1 | c.54C>T p.G18= | Silent (SNP) | VAF 16/42 reads (38%) | catalogued as COSV53278596; called by muse, mutect2, varscan2
- TAS2R9 | c.531T>C p.T177= | Silent (SNP) | VAF 49/195 reads (25%) | catalogued as COSV53688619; called by muse, mutect2, varscan2
- TCEANC | c.126T>C p.H42= (on ENST00000380600 / NM_001297563.2; = p.H72= on NM_152634.4) | Silent (SNP) | VAF 23/193 reads (12%) | catalogued as COSV59039660; called by muse, mutect2, varscan2
- TRIB3 | c.612G>A p.E204= | Silent (SNP) | VAF 7/39 reads (18%) | catalogued as rs769730097, COSV53930918; called by muse, mutect2, varscan2
- UBQLN4 | c.1557C>T p.A519= | Silent (SNP) | VAF 10/58 reads (17%) | catalogued as COSV100849352; called by muse, mutect2
- YLPM1 | c.6105C>T p.S2035= | Silent (SNP) | VAF 4/10 reads (40%) | catalogued as rs1487261591, COSV53110071; called by muse, mutect2, varscan2
- ZBTB40 | c.2379A>C p.G793= | Silent (SNP) | VAF 10/202 reads (5%) | catalogued as COSV100989043; called by muse, mutect2
- ZNF766 | c.84T>A p.P28= | Silent (SNP) | VAF 43/380 reads (11%) | catalogued as COSV63009307; called by muse, mutect2, varscan2
- ARMH4 | c.-2C>A | 5'UTR (SNP) | VAF 11/90 reads (12%) | catalogued as COSV99958502; called by muse, mutect2, varscan2
- CENPJ | c.*2G>T | 3'UTR (SNP) | VAF 84/304 reads (28%) | catalogued as COSV55042745, COSV55045920; called by muse, mutect2, varscan2
- DBN1 | c.86+1291C>T | Intron (SNP) | VAF 13/27 reads (48%) | catalogued as rs369476395; called by muse, mutect2, varscan2
- DCHS2 | n.3394T>C | RNA (SNP) | VAF 34/421 reads (8%) | catalogued as COSV100252275; called by muse, mutect2
- LINC00922 | n.849G>A | RNA (SNP) | VAF 141/332 reads (42%) | called by muse, mutect2, varscan2
- MARVELD3 | chr16:71640933 G>A | 3'Flank (SNP) | VAF 19/41 reads (46%) | catalogued as rs781617184, COSV51704549; called by muse, mutect2, varscan2
